TCGA case TCGA-Q1-A6DV — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Cervix uteri; Tissue source site: University of Oklahoma HSC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c80f777e-d150-40f3-9fa9-02ef9a6d7692

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 36 years; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma, endocervical type: ICD-O-3 morphology code: 8482/3; ICD-10 code: C53.0; Tissue or organ of origin: Endocervix; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 36.0 years (13,166 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 491 days (1.3 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Lymphatic invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, postoperative.

Follow-up (3 entries)
- Day -12 (preoperative): ECOG performance status: 0.
- Days to follow up: 491 days (1.3 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 113.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Current User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Initial Diagnosis; Weight: 60 kg; Height: 152 cm; BMI: 26.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-Q1-A6DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-Q1-A6DV-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
- Sample TCGA-Q1-A6DV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-Q1-A6DV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Total pregnancy count: 0; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Mucinous Adenocarcinoma of Endocervical Type; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Hysterectomy; Lymph nodes examined: Yes; Lymphovascular invasion: Absent; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 491 days; disease-specific survival: no event (censored), 491 days; disease-free interval: no event (censored), 491 days; progression-free interval: no event (censored), 491 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-Q1-A6DV-01A-11D-A32H-01): tumor purity 0.66, ploidy 2, whole-genome doublings 0.
